Somatic mutation profile of tumor specimen TCGA-G3-A25T-01A (aliquot TCGA-G3-A25T-01A-11D-A16V-10) from TCGA case TCGA-G3-A25T, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 45.1 years (16,461 days).
Specimen TCGA-G3-A25T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bb631f1-45ef-444f-9df8-ccb9d76ccdf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25T-10A (Blood Derived Normal), aliquot TCGA-G3-A25T-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62a8aa7d-b41a-4cef-a62e-0c91287dd6ed

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Intron 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.516G>C p.R172S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1057519736, COSV57468772, COSV57468910, COSV57481094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 17/26 reads (65%) | catalogued as CM1515070, COSV56230698; called by muse, mutect2, varscan2
- CD96 | c.1037C>G p.A346G (on ENST00000283285 / NM_198196.3; = p.A330G on NM_005816.5) | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51919085; called by muse, varscan2
- CDH2 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52287104; called by muse, mutect2, varscan2
- CST6 | c.269C>A p.T90K | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV56411554, COSV56411925; called by muse, varscan2
- FAM47A | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (1); PolyPhen possibly damaging (0.843); catalogued as COSV100649791, COSV60498240; called by muse, mutect2, varscan2
- FIBCD1 | c.884T>C p.F295S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53394418; called by muse, mutect2, varscan2
- INTU | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV56540808; called by muse, mutect2, varscan2
- LGR6 | c.2531G>A p.R844H (on ENST00000367278 / NM_001017403.1; = p.R792H on NM_021636.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs374809410; called by muse, mutect2, varscan2
- LRRC8A | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as rs752227637, COSV52187600; called by muse, mutect2, varscan2
- MYO1C | c.114T>G p.S38R (on ENST00000648651 / NM_001080779.2; = p.S3R on NM_033375.5) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV62999977; called by muse, mutect2, varscan2
- NOTCH2 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56697026; called by muse, mutect2
- NUDT5 | c.180T>C p.D60= | Splice Region (SNP) | VAF 34/78 reads (44%) | catalogued as rs763127956, COSV66718701; called by muse, mutect2
- PCID2 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55814299; called by muse, mutect2, varscan2
- PLBD2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55106030; called by muse, mutect2, varscan2
- PRKD2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV52188094; called by muse, mutect2, varscan2
- PYGM | c.894T>A p.Y298* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV51221493; called by muse, mutect2, varscan2
- RIMS1 | c.1090T>G p.Y364D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV53467563; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SPHK2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775661505, COSV55335820; called by muse, mutect2, varscan2
- SPIDR | c.1952C>G p.A651G | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52382396; called by muse, mutect2, varscan2
- STEAP1B | c.424A>G p.R142G | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68346919; called by muse, mutect2, varscan2
- TAS2R30 | c.641A>T p.K214I | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV67858627; called by muse, varscan2
- TYR | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747995722, CM085760, HM050006, COSV54480257; called by muse, mutect2, varscan2
- UNC13C | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs1448220871, COSV52896418; called by muse, mutect2, varscan2
- XRN2 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65870529; called by muse, mutect2, varscan2
- ZNF416 | c.1126C>G p.H376D | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52185044; called by muse, mutect2, varscan2
- ZNF532 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV60174362; called by muse, mutect2, varscan2
- ZZEF1 | c.5354G>T p.G1785V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67558735; called by muse, mutect2, varscan2
- AFG3L2 | c.2241del p.R748Dfs*93 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- H4C11 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TMCC1 | c.897_911delinsA p.H301Afs*36 | Frame Shift Del (DEL) | VAF 29/141 reads (21%) | called by pindel, varscan2*
- ZNF605 | c.15+4G>T | Splice Region (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- ABCD1 | c.318C>T p.F106= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54386352; called by muse, mutect2, varscan2
- AFG3L2 | c.2244A>G p.R748= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV52315871; called by mutect2, varscan2
- KIAA1109 | c.10666C>T p.L3556= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV52678424, COSV52682016; called by muse, mutect2, varscan2
- MYO18A | c.4638C>T p.D1546= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs752998128, COSV62869859; called by muse, mutect2, varscan2
- PAX8 | c.966C>T p.S322= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV54510463; called by muse, mutect2, varscan2
- PEG10 | c.819G>A p.P273= (on ENST00000482108 / NM_001040152.2; = p.P307= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, varscan2
- PLA2R1 | c.3717A>G p.R1239= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV51782191; called by muse, mutect2, varscan2
- SMG6 | c.888G>T p.V296= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV53970962; called by muse, mutect2, varscan2
- TNR | c.741C>T p.D247= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs756995159, COSV54875026, COSV54888003; called by muse, mutect2, varscan2
- TSC22D3 | c.81T>A p.S27= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV59778528; called by muse, mutect2, varscan2
- ZNF503 | c.831G>A p.T277= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV65307642; called by muse, varscan2
- PAX3 | chr2:222201413 C>T | 3'Flank (SNP) | VAF 21/56 reads (38%) | catalogued as rs753282124, COSV60590085; called by muse, varscan2
- TMEM128 | c.97+461G>A | Intron (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99632023; called by muse, mutect2, varscan2
- TTN | c.10361-4188G>A | Intron (SNP) | VAF 21/96 reads (22%) | catalogued as rs141483365; called by muse, mutect2, varscan2
